CPTAC case C3N-02694 — Other and unspecified parts of tongue — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Other and unspecified parts of tongue. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/af10dacb-24e8-4f8c-9210-d67b6a8a09b1

Demographics
Sex at birth: male; Race: white; Year of birth: 1960; Vital status: Dead; Days to death: 617 days (1.7 years); Year of death: 2019; Cause of death: Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Tongue, NOS; Site of resection or biopsy: Tongue, NOS; Age at diagnosis: 57.2 years (20,892 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N2b; AJCC pathologic M: MX; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 617 days (1.7 years); Progression or recurrence: no; Days to last follow up: 617 days (1.7 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.5 cm; Lymph node involvement: Positive; Lymph nodes positive: 2; Lymph nodes tested: 13; Lymphatic invasion present: No; Margin status: Involved; Perineural invasion present: No; Vascular invasion present: No.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (4 entries)
- Days to follow up: 464 days (1.3 years); Disease response: Tumor Free; Karnofsky performance status: 70; ECOG performance status: 1.
- Days to follow up: 538 days (1.5 years); Karnofsky performance status: 0.
- Days to follow up: 604 days (1.7 years); Disease response: Tumor Free; Karnofsky performance status: 70; ECOG performance status: 1.
- Days to follow up: 617 days (1.7 years); Disease response: With Tumor; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 93 kg; Height: 180 cm; BMI: 28.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified; Cigarettes per day: 15; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02694-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -5 days; Initial weight: 76 mg; Time between excision and freezing: 3 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02694-22: Section location: Tongue; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3N-02694-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -5 days; Initial weight: 57 mg; Time between excision and freezing: 3 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02694-23: Section location: Tongue; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3N-02694-12: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -5 days; Time between excision and freezing: 3 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-02694-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -4 days; Method of sample procurement: Blood Draw.
